Gene-level copy-number profile of tumor specimen TCGA-ER-A19C-06A from TCGA case TCGA-ER-A19C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 81.5 years (29,755 days).
Specimen TCGA-ER-A19C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.10eac022-7577-4a3b-bef6-2d3c3920a86c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A19C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9970fa6f-8353-49aa-b73b-e0ec2ce80e37

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 22,533; copy number 2: 30,130; copy number 3: 4,455; copy number 4: 1,124; copy number 5: 921; copy number 6: 201; copy number 7: 333; copy number 8: 108; copy number 9: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A19C-06A-11D-A194-01): tumor purity 0.8, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:139,668,547–139,825,877, 3 genes: MRPS18BP2, RPL9P13, AC078851.1.
- chr16:50,246,137–50,395,133, 5 genes: ADCY7, MIR6771, BRD7, AC007493.2, LINC02178.
- chr16:51,354,456–51,525,157, 1 gene (within-gene range 0–2): AC007344.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,567 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:53,764,204–55,743,152, 26 genes, copy number 7 (within-gene range 4–7): RNU6-449P, AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74, AC025272.1, AC011912.1, RSL24D1, RAB27A, AC018926.2, PIGBOS1, PIGB, CCPG1, AC018926.1, AC018926.3, DNAAF4-CCPG1, MIR628, C15orf65, DNAAF4, AC013355.1, PYGO1, AC012378.2, PRTG, AC012378.1.
- chr15:58,410,569–58,591,676, 6 genes, copy number 7: LIPC, LIPC-AS1, AC084781.1, AC084781.2, AC018904.2, AC018904.1.
- chr15:58,865,175–59,097,419, 1 gene, copy number 6 (within-gene range 4–6): RNF111.
- chr15:58,967,046–61,731,389, 58 genes, copy number 6: AC025918.2, AC092757.1, CCNB2, AC092757.3, AC092757.2, MYO1E, MIR2116, LDHAL6B, RNU4-80P, AC092756.1, RNU6-212P, AC092868.2, FAM81A, NSA2P4, AC092868.1, Y_RNA, AC092754.2, AC092754.1, RNA5SP396, GCNT3, GTF2A2, AC092755.1, BNIP2, PIGHP1, AC092755.2, RPS3AP6, AC092079.2, AC092079.1, NMNAT1P5, FOXB1, MESTP2, AC009654.1, AC037433.1, ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2, RORA-AS1, RORA, AC107241.1, CYCSP38, AC009560.1, AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1, AC022898.2, AC012404.1, AC012404.2, AC107905.1, AC104574.2, AC104574.1, AC018618.1, AC018618.2, LINC02349.
- chr15:67,254,786–68,820,897, 25 genes, copy number 5: IQCH, IQCH-AS1, C15orf61, AC016355.1, MAP2K5, HNRNPA1P5, SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11, AC100825.1, CORO2B, CARS1P1, ANP32A, MIR4312.
- chr15:68,833,830–68,834,749, 1 gene, copy number 5: AC087639.1.
- chr15:73,560,014–73,634,134, 1 gene, copy number 5 (within-gene range 3–5): NPTN.
- chr15:73,683,966–74,336,472, 25 genes, copy number 5: CD276, AC022188.1, INSYN1, INSYN1-AS1, AC018943.1, TBC1D21, LOXL1-AS1, LOXL1, STOML1, PML, AC013486.1, DNM1P33, GOLGA6A, RN7SL429P, COMMD4P2, ISLR2, AC010931.1, AC010931.2, Metazoa_SRP, ISLR, STRA6, CCDC33, AC023300.3, AC023300.1, AC023300.2.
- chr15:75,759,501–78,104,909, 54 genes, copy number 7 (within-gene range 4–7): AC019294.3, MIR4313, AC019294.1, RN7SL319P, DNM1P49, UBE2Q2, RN7SL510P, FBXO22, NRG4, AC027104.1, TMEM266, AC091100.1, ETFA, Metazoa_SRP, TYRO3P, AC027243.3, ISL2, AC027243.1, AC027243.2, SCAPER, AC090751.1, MIR3713, RN7SKP217, RCN2, RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1, AC046168.1, AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1, CSPG4P13, AC104758.2, AC104758.3, RN7SL214P, COMMD4P1, AC104758.4, ADAMTS7P3, TBC1D2B, AC104758.1, SH2D7, SNORA63.
- chr15:80,404,350–80,597,933, 1 gene, copy number 6 (within-gene range 4–6): ARNT2.
- chr15:82,543,201–84,126,604, 39 genes, copy number 5 (within-gene range 4–5): CPEB1, CPEB1-AS1, AP3B2, AC105339.4, AC105339.1, ACTG1P17, AC105339.5, AC105339.3, AC105339.6, SNHG21, AC105339.2, FSD2, SCARNA15, WHAMM, HOMER2, AC022558.2, RAMAC, C15orf40, AC024270.3, BTBD1, AC022558.3, AC022558.1, AC024270.1, FABP5P8, MIR4515, AC024270.4, TM6SF1, HDGFL3, AC024270.2, AC103876.1, BNC1, SH3GL3, ADAMTSL3, RNU6-401P, TUBAP4, RNU6-1339P, AC027807.2, AC027807.1, EFL1P1.
- chr15:85,380,571–85,749,358, 1 gene, copy number 5 (within-gene range 4–5): AKAP13.
- chr15:85,579,046–89,951,345, 94 genes, copy number 5–8 (broad region; genes not listed).
- chr15:90,006,755–90,006,841, 1 gene, copy number 8: MIR3174.
- chr15:94,231,538–95,169,864, 11 genes, copy number 6–9: MCTP2, AC135626.1, AC135626.2, AC009432.2, LINC02852, AC009432.1, AC022308.1, AC087633.2, AC107976.1, AC087633.1, AC087636.1.
- chr15:95,225,326–95,225,864, 1 gene, copy number 9: AC104260.1.
- chr15:96,325,938–96,496,462, 12 genes, copy number 6: NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP.
- chr15:99,971,437–100,342,005, 1 gene, copy number 7 (within-gene range 1–7): ADAMTS17.
- chr15:100,074,081–101,933,350, 59 genes, copy number 7: RNA5SP402, AC022710.1, SPATA41, CERS3-AS1, CERS3, AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2, LRRK1, AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr16:8,276,263–15,643,154, 197 genes, copy number 5–6 (broad region; genes not listed).
- chr16:15,643,294–15,643,372, 1 gene, copy number 5: MIR484.
- chr16:16,499,533–19,401,693, 68 genes, copy number 6 (broad region; genes not listed).
- chr16:19,410,729–19,411,662, 1 gene, copy number 6: AC130456.4.
- chr22:15,290,718–23,929,574, 514 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr22:27,414,462–28,679,865, 20 genes, copy number 5 (within-gene range 1–5): AL049536.1, AL050402.2, AL050402.1, AL133456.1, AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA.
- chr22:35,400,134–35,729,483, 10 genes, copy number 5: MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5.
- chr22:36,847,372–43,513,727, 272 genes, copy number 5–7 (broad region; genes not listed).
- chr22:43,528,744–44,862,788, 29 genes, copy number 7 (within-gene range 3–7): EFCAB6, Z97055.1, HMGN2P9, Z97055.2, SULT4A1, PNPLA5, PNPLA3, SAMM50, RPL35AP36, PARVB, AL033543.1, AL031595.3, PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1, Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8.
- chr22:48,044,710–49,890,080, 38 genes, copy number 8 (within-gene range 2–8): FP325330.1, FP325330.2, BX284656.2, BX284656.1, AL008720.1, MIR3201, AL008720.2, Z72006.1, Z82249.1, Z84468.2, TAFA5, Z84468.1, MIR4535, LINC01310, AL078622.1, Z82202.2, RPL35P8, Z82202.1, AC207130.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, Z97192.4, AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4.

Autosomal genes at a single copy (total copy number 1): 20,146. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
